Somatic mutation profile of tumor specimen TCGA-DK-A1A6-06A (aliquot TCGA-DK-A1A6-06A-11D-A42E-08) from TCGA case TCGA-DK-A1A6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 53.5 years (19,554 days).
Specimen TCGA-DK-A1A6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) febc948a-20af-4929-8c55-8fd8afca5fc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1A6-10A (Blood Derived Normal), aliquot TCGA-DK-A1A6-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/151e424f-6e31-4413-a50f-709ccba12d1a

The open-access MAF lists 297 somatic variants for this specimen: 232 protein-altering or splice-affecting, 59 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 59, Nonsense Mutation 20, Splice Site 9, Frame Shift Ins 4, RNA 3, Nonstop Mutation 2, Splice Region 2, Frame Shift Del 2, Intron 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 33/89 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.371dup p.C124Wfs*25 | Frame Shift Ins (INS) | VAF 28/51 reads (55%) | catalogued as rs1267047192, COSV53205177; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACCS | c.221G>A p.W74* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99772748; called by muse, mutect2, varscan2
- ACTB | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59316730; called by muse, mutect2, varscan2
- ADAM19 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs755895049, COSV57423019; called by muse, varscan2
- ADAM22 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs752694897, COSV55969207; called by muse, mutect2, varscan2
- ADAM30 | c.1732C>G p.H578D | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV65560342; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1258C>A p.P420T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54436296; called by muse, mutect2, varscan2
- ADRA1A | c.366C>G p.I122M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52356845, COSV52357087; called by muse, mutect2, varscan2
- AGBL1 | c.2424C>A p.S808R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1430366786, COSV66848871; called by muse, mutect2, varscan2
- AGL | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV54048224; called by muse, mutect2, varscan2
- ALPK1 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs762385585, COSV51581923; called by muse, mutect2, varscan2
- AMY2A | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 31/263 reads (12%) | catalogued as COSV101340623; called by muse, mutect2, varscan2
- ANK1 | c.5545G>C p.V1849L (on ENST00000347528 / NM_020477.3; = p.X1848_splice on NM_000037.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV55872866; called by muse, mutect2, varscan2
- APOB | c.9692A>G p.D3231G | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs778780703, COSV51923418; called by muse, mutect2, varscan2
- ARNT | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62229668; called by muse, varscan2
- AUTS2 | c.3506C>G p.S1169C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV61383299; called by muse, mutect2, varscan2
- AVL9 | c.1946G>C p.*649Sext*13 | Nonstop Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100594545; called by muse, mutect2, varscan2
- BRD8 | c.2703G>C p.W901C | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV50145211; called by muse, mutect2, varscan2
- BRWD1 | c.4314C>G p.F1438L | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV60892728; called by muse, mutect2, varscan2
- BTBD7 | c.970T>C p.Y324H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54133888; called by muse, mutect2, varscan2
- BZW2 | c.1232-1G>C p.X411_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as COSV51753861; called by muse, mutect2, varscan2
- C1orf56 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs1461699890, COSV54845741; called by muse, varscan2
- C3 | c.3543G>A p.M1181I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55568652; called by muse, mutect2, varscan2
- C9orf64 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV59032116; called by muse, mutect2, varscan2
- CCDC110 | c.1652A>G p.H551R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.463); catalogued as rs1197000498, COSV56869399; called by muse, mutect2, varscan2
- CCDC181 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs375735868; called by muse, mutect2, varscan2
- CCDC40 | c.2150C>G p.S717C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV66472694; called by mutect2, varscan2
- CCDC40 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV66472702; called by muse, mutect2, varscan2
- CCDC71 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58909742; called by muse, mutect2, varscan2
- CD248 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as rs200653218, COSV60935719; called by muse, mutect2, varscan2
- CDCA7L | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60939981; called by muse, mutect2, varscan2
- CDCA7L | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV100651146, COSV62258105; called by muse, mutect2, varscan2
- CFAP54 | c.5176C>G p.L1726V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV61570579, COSV61572992; called by muse, mutect2, varscan2
- CH25H | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs1424643708, COSV64092195; called by muse, mutect2, varscan2
- CNN1 | c.76T>C p.Y26H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV99372276; called by muse, mutect2
- COQ6 | c.1369C>G p.P457A | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV53177932; called by muse, mutect2, varscan2
- CPEB2 | c.2092G>T p.D698Y | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52589355, COSV52594540; called by muse, mutect2, varscan2
- CPS1 | c.2253G>C p.K751N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV51802122; called by muse, mutect2, varscan2
- CTAG2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV55994023; called by muse, mutect2, varscan2
- DAGLA | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.953); catalogued as rs1409547344, COSV57193994; called by muse, mutect2
- DBF4 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV55995841; called by muse, mutect2, varscan2
- DDC | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.234); catalogued as COSV63563711; called by muse, mutect2, varscan2
- DDX21 | c.2023C>G p.L675V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV62555154; called by muse, mutect2, varscan2
- DDX60 | c.881A>T p.Q294L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV67095098; called by muse, mutect2
- DHDDS | c.324-1G>A p.X108_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV52575451; called by muse, mutect2, varscan2
- DHX37 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1253670476, COSV58131924; called by muse, mutect2, varscan2
- DIDO1 | c.5471G>C p.R1824T | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV56613790, COSV56619336; called by muse, mutect2, varscan2
- DNAH3 | c.7814A>G p.N2605S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.699); catalogued as rs969114762, COSV54503459; called by muse, mutect2, varscan2
- DNASE2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV53434443, COSV53435844; called by muse, mutect2, varscan2
- DST | c.4896G>C p.E1632D | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV54997759, COSV99754072; called by muse, mutect2, varscan2
- DST | c.4762G>C p.E1588Q | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as rs1202435794, COSV54997767; called by muse, mutect2, varscan2
- EEA1 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59282612; called by muse, mutect2, varscan2
- EEFSEC | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1370773717, COSV54620147; called by muse, mutect2, varscan2
- EIF4G1 | c.2407G>C p.E803Q (on ENST00000346169 / NM_198241.3; = p.E608Q on NM_004953.5) | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV59989182; called by muse, mutect2, varscan2
- ELAVL4 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV63914275; called by muse, mutect2, varscan2
- EMILIN2 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs753375646, COSV54421112; called by muse, mutect2, varscan2
- EP400 | c.4004C>T p.P1335L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57762832; called by muse, mutect2, varscan2
- EPB41 | c.2416-1G>C p.X806_splice (on ENST00000343067 / NM_001166005.2; = p.X530_splice on NM_004437.4) | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as COSV58040877; called by muse, mutect2, varscan2
- EPHB3 | c.2900G>T p.R967L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100382769, COSV100382908; called by muse, mutect2, varscan2
- EPS15 | c.1215A>C p.K405N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765028884, COSV65540397; called by muse, mutect2, varscan2
- ESRP2 | c.1006G>C p.E336Q (on ENST00000565858 / NM_001365264.1; = p.E326Q on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52171951; called by muse, mutect2, varscan2
- ETV6 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1478954275, COSV67148178; called by muse, varscan2
- ETV6 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV67148182; called by muse, varscan2
- EXPH5 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV56198909; called by muse, mutect2
- EYA2 | c.156-1G>C p.X52_splice | Splice Site (SNP) | VAF 44/70 reads (63%) | catalogued as COSV57938469; called by muse, mutect2, varscan2
- FANCE | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs759034838, COSV57689081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAP | c.1026C>A p.S342R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV51859320; called by muse, mutect2
- FBXO25 | c.338C>G p.S113* (on ENST00000382824 / NM_183421.2; = p.S46* on NM_012173.3) | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99366822; called by muse, mutect2, varscan2
- FERMT2 | c.1020C>G p.D340E | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV58405126; called by muse, varscan2
- FGF3 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 33/575 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs150581924, COSV61925255; called by muse, mutect2
- FREM2 | c.6763G>A p.E2255K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as rs1185209837, COSV54828425, COSV54855715; called by muse, varscan2
- FREM2 | c.6866G>C p.R2289T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as rs777079243, COSV54828444; called by muse, varscan2
- GABRB1 | c.1387C>T p.L463F | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV54970778; called by muse, mutect2, varscan2
- GABRG1 | c.1153G>T p.G385* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV54952990, COSV99777656; called by muse, mutect2
- GCC2 | c.2659C>G p.Q887E | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs775980873, COSV59174002; called by muse, mutect2, varscan2
- GPR89A | c.925G>C p.V309L | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as COSV100572399; called by muse, varscan2
- GPR89A | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as COSV100572397; called by muse, varscan2
- GRM3 | c.1970C>G p.S657* | Nonsense Mutation (SNP) | VAF 41/113 reads (36%) | catalogued as COSV100862303; called by muse, mutect2, varscan2
- H2AC13 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100704334; called by muse, mutect2
- HARBI1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV56317448; called by muse, mutect2, varscan2
- HCFC1R1 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50187193; called by muse, mutect2, varscan2
- HLA-DRA | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV66622508; called by muse, mutect2, varscan2
- HMGA1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.932); catalogued as COSV61028958; called by muse, mutect2
- HTRA3 | c.483G>A p.L161= | Splice Region (SNP) | VAF 8/20 reads (40%) | catalogued as COSV56469306; called by muse, mutect2, varscan2
- INSRR | c.635G>C p.R212T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100947955, COSV63870918; called by muse, mutect2, varscan2
- IRF2BPL | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as COSV53146048; called by muse, mutect2, varscan2
- ITPR3 | c.1398G>C p.Q466H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV65405705; called by muse, mutect2, varscan2
- IVD | c.476G>A p.G159D (on ENST00000651168; = p.G156D on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM087373, COSV51098701; called by muse, mutect2, varscan2
- JAK3 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1471740073, COSV71685529; called by muse, mutect2, varscan2
- KCNU1 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV67753115; called by muse, mutect2, varscan2
- KHDRBS2 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs771240471, COSV55427315; called by muse, mutect2, varscan2
- KIAA0319L | c.2326G>C p.D776H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57842004, COSV57851877; called by muse, mutect2, varscan2
- KMT5B | c.1004G>C p.R335T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV58563729; called by muse, mutect2
- LAMB2 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1131783, COSV59730824; called by muse, mutect2, varscan2
- LAMC1 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.695); catalogued as rs750433323, COSV51132544; called by muse, mutect2, varscan2
- LARGE1 | c.930G>T p.M310I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV61657808; called by muse, mutect2, varscan2
- LMNTD2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs374391484; called by muse, mutect2, varscan2
- LRFN5 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV53243340, COSV53258853; called by muse, mutect2, varscan2
- LRIT1 | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as COSV64511926, COSV64513711; called by muse, mutect2
- LRRC6 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51537910; called by muse, mutect2, varscan2
- LTBP2 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761149592, COSV56204903; called by muse, mutect2, varscan2
- MAP3K13 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as rs763461574, COSV53983703; called by muse, mutect2, varscan2
- MAP3K21 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145103476; called by muse, mutect2, varscan2
- MAPK8IP1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53796676; called by muse, mutect2, varscan2
- MAPK9 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100558224; called by muse, mutect2, varscan2
- MBD6 | c.2164C>G p.L722V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV63072983; called by muse, mutect2, varscan2
- MON2 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV54803026; called by muse, mutect2, varscan2
- MRE11 | c.1326+1G>C p.X442_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV60573877; called by muse, mutect2, varscan2
- MROH8 | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV54117260; called by muse, mutect2, varscan2
- MT1H | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV60090520; called by muse, mutect2, varscan2
- MTIF2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55050203; called by muse, mutect2, varscan2
- MTRF1 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV65262834; called by muse, mutect2, varscan2
- MXD4 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as rs1218355505, COSV61465774; called by muse, mutect2, varscan2
- MXD4 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100455865; called by muse, mutect2
- MYH7B | c.1566C>G p.I522M | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53416555, COSV53421379; called by muse, mutect2, varscan2
- MYLK2 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); catalogued as COSV101044591, COSV65658512; called by muse, mutect2, varscan2
- MYO15A | c.804C>A p.S268R | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1392414832, COSV52751804; called by muse, mutect2, varscan2
- MYO5A | c.2096C>G p.S699* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as rs753464756, COSV100697481; called by muse, mutect2, varscan2
- MYPOP | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV56192879; called by muse, mutect2, varscan2
- MYT1L | c.1272C>A p.F424L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV67708347, COSV67709367; called by muse, mutect2, varscan2
- NLRP9 | c.909G>C p.K303N | Missense Mutation (SNP) | VAF 82/117 reads (70%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV60459618; called by muse, varscan2
- NUTM2G | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs541253499, COSV63616879; called by muse, mutect2, varscan2
- OR52N4 | c.783C>G p.F261L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV57890271, COSV57893523; called by muse, mutect2, varscan2
- OR5K2 | c.831A>T p.L277F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV71143031; called by muse, mutect2, varscan2
- OR6C6 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV64455451, COSV64455971; called by muse, mutect2, varscan2
- OSBPL1A | c.2584G>C p.D862H (on ENST00000319481 / NM_080597.4; = p.D349H on NM_018030.4) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as COSV60195312; called by muse, mutect2, varscan2
- OSBPL3 | c.2069T>C p.I690T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57652673; called by muse, mutect2
- PAH | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.922); catalogued as rs868854935, COSV61013953; called by muse, mutect2, varscan2
- PCDH10 | c.1140del p.F380Lfs*3 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as COSV52087594, COSV52096631; called by mutect2, pindel, varscan2
- PCLO | c.11269A>G p.M3757V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as rs764159984, COSV61616363; called by muse, mutect2, varscan2
- PCOLCE2 | c.1010C>G p.S337W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs2304735, COSV55997592; called by muse, mutect2, varscan2
- PDZD2 | c.2933G>C p.R978T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV56850811; called by muse, mutect2, varscan2
- PHF20L1 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 66/133 reads (50%) | catalogued as COSV99620765; called by muse, mutect2, varscan2
- PKD1L1 | c.4795C>G p.L1599V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1245542767, COSV56958004; called by muse, mutect2, varscan2
- PKD1L2 | c.773T>A p.M258K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV61411645; called by muse, mutect2, varscan2
- PLCG1 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1434096207, COSV54815258, COSV99718437; called by muse, mutect2
- PLG | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.858); catalogued as COSV51980698, COSV51983082; called by muse, varscan2
- PLIN3 | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV55734084; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs1450946602, COSV65046981; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1315A>C p.N439H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV65046989; called by muse, mutect2, varscan2
- POLE | c.5143G>A p.E1715K | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.716); catalogued as rs1368719601, COSV57673180, COSV57674238; called by muse, varscan2
- POLE | c.4883G>C p.G1628A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1233643471, COSV57674250; called by muse, mutect2, varscan2
- PPP4R3B | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55401749; called by muse, mutect2, varscan2
- PRDM4 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs940716413, COSV57304478; called by muse, mutect2, varscan2
- PREX2 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV99906094; called by muse, mutect2, varscan2
- PRKD2 | c.2345A>G p.D782G | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1206670046, COSV52184534; called by muse, mutect2, varscan2
- PRKDC | c.3127C>G p.Q1043E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58042868; called by muse, mutect2, varscan2
- PTPN13 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368764035; called by muse, mutect2, varscan2
- PTPN21 | c.2749C>T p.R917* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs780993226, COSV60852584; called by muse, varscan2
- PTPRT | c.2617G>T p.D873Y | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61960753; called by muse, mutect2, varscan2
- PTPRZ1 | c.3761C>G p.S1254C | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV66430348; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs779969064, COSV99424560; called by muse, mutect2, varscan2
- RABEP2 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs1269198047, COSV100706919; called by muse, mutect2, varscan2
- RAPGEF6 | c.4381G>T p.E1461* | Nonsense Mutation (SNP) | VAF 21/123 reads (17%) | catalogued as COSV99725823; called by muse, mutect2, varscan2
- RIPOR1 | c.760G>C p.D254H (on ENST00000379312 / NM_001193522.2; = p.D250H on NM_024519.4) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50217237, COSV99242386; called by muse, mutect2, varscan2
- ROCK1 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV101296291; called by muse, varscan2
- RPGR | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV58832479, COSV58833345; called by muse, mutect2, varscan2
- RYR2 | c.7565C>T p.T2522I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.218); catalogued as COSV63662245; called by muse, mutect2, varscan2
- SAMD9 | c.1255A>G p.K419E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66072994; called by muse, mutect2, varscan2
- SASH1 | c.2599G>C p.E867Q | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV66558873; called by muse, mutect2, varscan2
- SETD4 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV59771160; called by muse, mutect2, varscan2
- SFPQ | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100599277; called by muse, mutect2, varscan2
- SFSWAP | c.521-1G>C p.X174_splice | Splice Site (SNP) | VAF 19/39 reads (49%) | catalogued as COSV55519449; called by muse, mutect2, varscan2
- SGSM3 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50651196; called by muse, mutect2, varscan2
- SIGLEC10 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV59478916; called by muse, mutect2, varscan2
- SIRPG | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1281567353, COSV53805960; called by muse, mutect2, varscan2
- SLC22A12 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as COSV60570831; called by muse, mutect2, varscan2
- SLC33A1 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs149578822; called by muse, mutect2, varscan2
- SLC7A6OS | c.848G>C p.R283T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV50449864; called by muse, mutect2, varscan2
- SOSTDC1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752502638, COSV61048982; called by muse, mutect2, varscan2
- SP100 | c.2281C>A p.H761N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.474); catalogued as COSV60841764; called by muse, mutect2, varscan2
- SPIDR | c.2282C>A p.P761Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52369630; called by muse, mutect2, varscan2
- SPTAN1 | c.2479C>T p.Q827* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV63985980; called by muse, mutect2, varscan2
- ST8SIA3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | PolyPhen probably damaging (0.993); catalogued as rs532770217, COSV60653316; called by muse, mutect2, varscan2
- STEAP4 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as rs554141706, COSV57328031; called by muse, mutect2, varscan2
- STK33 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.53); catalogued as COSV59396540; called by muse, mutect2, varscan2
- STK33 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.219); catalogued as COSV59396548, COSV59401196; called by muse, mutect2, varscan2
- SUGP1 | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV55920281; called by muse, mutect2, varscan2
- SULT1C2 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52263727; called by muse, mutect2, varscan2
- SYMPK | c.1306C>G p.P436A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55609575; called by muse, mutect2, varscan2
- SYNE1 | c.3535G>A p.E1179K (on ENST00000367255 / NM_182961.4; = p.E1186K on NM_033071.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs775925423, COSV54907232; called by muse, mutect2, varscan2
- TAAR8 | c.636G>C p.M212I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV51585586; called by mutect2, varscan2
- TAGLN3 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as rs748629105, COSV56327064; called by muse, mutect2, varscan2
- TBC1D16 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60475380; called by muse, mutect2, varscan2
- TENM1 | c.7349T>C p.L2450S | Missense Mutation (SNP) | VAF 65/87 reads (75%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV64425208; called by muse, mutect2, varscan2
- TET1 | c.3578C>G p.S1193W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65382039; called by muse, mutect2, varscan2
- TFAP2A | c.193C>T p.Q65* (on ENST00000482890; = p.Q57* on NM_001032280.3) | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100116695; called by muse, mutect2, varscan2
- TMCO6 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 25/47 reads (53%) | catalogued as COSV99347054; called by muse, mutect2, varscan2
- TMPRSS15 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV53034828; called by muse, mutect2, varscan2
- TMTC2 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs147409383; called by muse, mutect2, varscan2
- TRMT13 | c.1101G>C p.M367I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV61582667; called by muse, mutect2, varscan2
- TRPA1 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV51555483; called by muse, mutect2, varscan2
- TRPM6 | c.4610C>T p.A1537V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV62502996; called by muse, mutect2, varscan2
- TTBK2 | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV51157338; called by muse, mutect2, varscan2
- TTN | c.72671G>A p.G24224D (on ENST00000591111; = p.G16800D on NM_003319.4) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | PolyPhen benign (0.005); catalogued as rs756930121, COSV59889464; called by muse, mutect2
- TXNDC9 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51810884; called by muse, mutect2
- UBQLN2 | c.576G>C p.Q192H | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57739035; called by muse, mutect2, varscan2
- UBR4 | c.6718C>T p.R2240C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1210377000, COSV64382867; called by muse, mutect2
- ULBP1 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV57663489; called by muse, mutect2, varscan2
- USB1 | c.595A>T p.T199S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV54682322; called by muse, mutect2, varscan2
- USF3 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV57069834; called by muse, mutect2, varscan2
- USP53 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1308963191, COSV56792300; called by muse, mutect2, varscan2
- VIPR2 | c.1102-1G>A p.X368_splice | Splice Site (SNP) | VAF 17/53 reads (32%) | catalogued as rs1280385667, COSV51103354; called by muse, mutect2, varscan2
- WDHD1 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1388416561, COSV62212860; called by muse, mutect2, varscan2
- WDR41 | c.862C>G p.H288D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV56997621; called by muse, mutect2, varscan2
- XPO7 | c.1275G>A p.L425= | Splice Region (SNP) | VAF 15/52 reads (29%) | catalogued as COSV53010725; called by muse, mutect2, varscan2
- YTHDF3 | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV101572369; called by muse, mutect2, varscan2
- ZBTB5 | c.1348C>G p.P450A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV57038848; called by muse, mutect2, varscan2
- ZDBF2 | c.2566G>C p.E856Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV65621932; called by muse, mutect2
- ZFHX4 | c.357A>C p.L119F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as COSV50495653; called by muse, mutect2, varscan2
- ZNF500 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV54787041; called by muse, mutect2, varscan2
- ZNF624 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60938888; called by muse, mutect2, varscan2
- ZNF624 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV60938901; called by muse, varscan2
- ZNF624 | c.887G>C p.R296T | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV60938972, COSV60941620; called by muse, mutect2, varscan2
- ZNF624 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60939037; called by muse, varscan2
- ZNF721 | c.1187A>C p.K396T (on ENST00000338977; = p.K408T on NM_133474.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV59089150; called by mutect2, varscan2
- ZNF75A | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV73039560; called by muse, mutect2, varscan2
- ZNF99 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV68054748; called by muse, mutect2, varscan2
- ZNF99 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68054753; called by muse, mutect2, varscan2
- ZP4 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.105); catalogued as rs1021008107, COSV63910918; called by muse, mutect2, varscan2
- ZPLD1 | c.1064C>T p.S355L (on ENST00000466937 / NM_001329788.1; = p.S371L on NM_175056.2) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs369331610; called by muse, mutect2, varscan2
- ZSWIM8 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV67131097; called by muse, mutect2, varscan2
- IGKC | c.324G>C p.*108Yext*59 | Nonstop Mutation (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- KDM6A | c.3875_3878+3del p.X1292_splice | Splice Site (DEL) | VAF 22/43 reads (51%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.336+7_336+8del p.X112_splice | Splice Site (DEL) | VAF 20/53 reads (38%) | called by pindel, varscan2
- NEIL3 | c.994_1005del p.P332_K335del | In Frame Del (DEL) | VAF 19/133 reads (14%) | called by mutect2, pindel, varscan2
- PPP1R3C | c.327_337del p.W110Vfs*2 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- QSER1 | c.5119C>T p.Q1707* (on ENST00000399302; = p.Q1836* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- TXNIP | c.979dup p.T327Nfs*14 | Frame Shift Ins (INS) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- ZNF48 | c.1825dup p.L609Pfs*61 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by mutect2, pindel
- ZNF624 | c.756dup p.G253Rfs*19 | Frame Shift Ins (INS) | VAF 58/155 reads (37%) | called by pindel, varscan2
- ABHD14A-ACY1 | c.786C>G p.L262= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV56472171; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2365C>T p.L789= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV54436312, COSV54459568; called by muse, mutect2, varscan2
- BMP1 | c.765G>A p.Q255= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV60476319; called by muse, mutect2, varscan2
- C12orf43 | c.507C>T p.S169= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs746220744, COSV56566269; called by muse, mutect2
- CASZ1 | c.817C>T p.L273= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV59732068; called by muse, mutect2, varscan2
- CCT8L2 | c.1440G>A p.V480= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV63461634, COSV63462331; called by muse, mutect2, varscan2
- CFAP54 | c.5310C>T p.F1770= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs768774190, COSV61570582; called by muse, mutect2, varscan2
- CNTN2 | c.2928C>T p.D976= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV59348109; called by muse, mutect2, varscan2
- COL6A2 | c.201C>G p.L67= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV55998820; called by muse, mutect2, varscan2
- CRP | c.480C>T p.F160= | Silent (SNP) | VAF 36/170 reads (21%) | catalogued as rs374947007, COSV54812594; called by muse, mutect2, varscan2
- CRTC2 | c.1800C>T p.F600= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV57841052, COSV57841860; called by muse, mutect2, varscan2
- CSTF2 | c.955C>A p.R319= | Silent (SNP) | VAF 26/35 reads (74%) | catalogued as COSV65893447, COSV65895238; called by muse, mutect2, varscan2
- DNAH5 | c.1518C>T p.D506= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV54204254; called by muse, mutect2, varscan2
- DNAH8 | c.3060G>A p.V1020= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1469003636, COSV59425180; called by muse, mutect2, varscan2
- DOCK2 | c.5184G>A p.E1728= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV56942186; called by muse, mutect2, varscan2
- DOT1L | c.2931C>T p.T977= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs762151259, COSV67107968; called by muse, mutect2, varscan2
- DUSP15 | c.780C>T p.T260= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1172530105, COSV54064898; called by muse, mutect2, varscan2
- F5 | c.2391C>G p.A797= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV63120476; called by muse, mutect2, varscan2
- FADS6 | c.402C>T p.F134= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1357030614, COSV59603038; called by muse, mutect2
- FAM47A | c.1737C>T p.Y579= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as COSV60494016; called by muse, mutect2, varscan2
- FLG | c.11331G>A p.S3777= | Silent (SNP) | VAF 85/329 reads (26%) | catalogued as rs147295587, COSV64240789; called by muse, mutect2, varscan2
- FLT1 | c.663C>G p.L221= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV56717848; called by muse, mutect2
- GALNT6 | c.1014G>A p.E338= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV62541623; called by muse, mutect2, varscan2
- HAUS8 | c.753C>T p.S251= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV53725283; called by muse, varscan2
- HIRIP3 | c.1670G>A p.*557= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99662929; called by muse, mutect2, varscan2
- HTR3A | c.1296G>C p.R432= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV55467998; called by muse, mutect2, varscan2
- KCNJ11 | c.333C>T p.V111= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV60594164; called by muse, mutect2, varscan2
- LEXM | c.726G>C p.R242= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV64022049; called by muse, mutect2
- LIPJ | c.573C>T p.V191= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as rs779631757, COSV64245027; called by muse, mutect2, varscan2
- MAGEA4 | c.234C>T p.F78= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV52340234; called by muse, mutect2, varscan2
- MYCT1 | c.417G>C p.L139= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV65890806; called by muse, mutect2, varscan2
- MYPN | c.1596G>C p.V532= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV62731601; called by muse, mutect2, varscan2
- NAT9 | c.501C>T p.S167= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV52852515; called by muse, mutect2, varscan2
- NDRG4 | c.291C>G p.P97= (on ENST00000570248 / NM_001378344.1; = p.P129= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV50746425, COSV50748169; called by muse, varscan2
- NLRP9 | c.1041G>A p.V347= | Silent (SNP) | VAF 88/110 reads (80%) | catalogued as rs146611098, COSV60459598; called by muse, varscan2
- OR10C1 | c.669C>A p.L223= (on ENST00000622521; = p.L221= on NM_013941.3) | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV65822243, COSV65822605; called by muse, mutect2, varscan2
- OR52E2 | c.977G>A p.*326= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV58613034; called by muse, mutect2, varscan2
- OTUD4 | c.1812T>C p.F604= (on ENST00000447906 / NM_001366057.1; = p.F539= on NM_001102653.1) | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as rs375195266; called by muse, mutect2, varscan2
- OVGP1 | c.382C>T p.L128= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV63857534; called by muse, mutect2, varscan2
- P2RX3 | c.15C>T p.S5= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs748037477, COSV53478229; called by mutect2, varscan2
- PEX6 | c.1314G>C p.L438= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV55101740; called by mutect2, varscan2
- PFDN6 | c.84G>A p.S28= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV65841932; called by muse, mutect2, varscan2
- PLCB1 | c.1056G>C p.V352= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV62038396; called by muse, mutect2, varscan2
- PTPRD | c.747A>T p.P249= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV61928720; called by muse, mutect2, varscan2
- RBM4 | c.309G>A p.P103= | Silent (SNP) | VAF 103/167 reads (62%) | catalogued as rs775441815, COSV59518051; called by muse, mutect2, varscan2
- SDK1 | c.2397G>T p.G799= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs202017032, COSV67356699; called by muse, mutect2, varscan2
- SEC13 | c.201C>T p.H67= (on ENST00000350697 / NM_183352.3; = p.H70= on NM_030673.4) | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs1217147600, COSV61601220; called by muse, mutect2, varscan2
- SEPTIN4 | c.1245T>A p.P415= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV58727097; called by muse, mutect2, varscan2
- SHISA3 | c.477C>T p.S159= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV59979427; called by muse, mutect2, varscan2
- SLC2A1 | c.1014C>T p.L338= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV65286713; called by muse, mutect2, varscan2
- SLIT1 | c.708C>T p.I236= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs900242418, COSV99820935; called by muse, mutect2, varscan2
- SPTAN1 | c.2286C>T p.L762= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs745436802, COSV63985443; called by muse, varscan2
- TEK | c.600C>T p.T200= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV66227468; called by muse, mutect2, varscan2
- TPCN1 | c.465C>T p.L155= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV59232339; called by muse, mutect2, varscan2
- TRMT2A | c.1515C>T p.L505= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs762744801, COSV52812359; called by muse, mutect2, varscan2
- TXNRD2 | c.1026G>A p.L342= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as rs777442456, COSV68691442; called by muse, mutect2, varscan2
- WDPCP | c.306C>T p.D102= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV55413087; called by muse, mutect2, varscan2
- XIRP2 | c.5037G>A p.Q1679= (on ENST00000628543; = p.Q1854= on NM_152381.6) | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV54682900; called by muse, mutect2, varscan2
- ZCCHC4 | c.765C>T p.A255= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV57180230; called by muse, mutect2, varscan2
- AC073310.1 | n.980C>A | RNA (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- CCN6 | c.-23-20G>T | Intron (SNP) | VAF 19/48 reads (40%) | catalogued as COSV57888756; called by muse, mutect2, varscan2
- CD48 | c.*1G>A | 3'UTR (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100924203; called by muse, mutect2
- EEF1D | c.-7-2778G>A | Intron (SNP) | VAF 5/15 reads (33%) | catalogued as COSV57817543; called by muse, mutect2, varscan2
- MIR545 | n.26C>T | RNA (SNP) | VAF 9/10 reads (90%) | called by muse, mutect2, varscan2
- NBPF25P | n.1423C>G | RNA (SNP) | VAF 68/269 reads (25%) | called by muse, mutect2, varscan2
